TCGA case TCGA-DD-AAE6 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a61f823b-9164-4bd6-92f4-0a8d8ff0f55e

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 59.6 years (21,764 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 141 days; Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 59.9 years (21,869 days); Days to diagnosis: 105 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 105 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 105 days.
- Days to follow up: 141 days; Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Total Bilirubin 0.9 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 113 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Platelets 209 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.8; Blood test normal range upper: 5.3].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 1; Blood test normal range upper: 1].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 46 kg; Height: 159 cm; BMI: 18.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AAE6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-DD-AAE6-01A-01-TS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 1; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-AAE6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AAE6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 141 days; disease-specific survival: no event (censored), 141 days; disease-free interval: event (new tumor event after initially disease-free), 105 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 105 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AAE6-01A-11D-A40Q-01): tumor purity 0.98, ploidy 4.21, whole-genome doublings 1.
